TARGET case TARGET-15-SJMPAL012421 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2f4c8bf3-d67a-4719-90c7-6bb270c30799

Demographics
Sex at birth: female; Age at index: 12 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 12.3 years (4,484 days); Year of diagnosis: 2005; Days to last follow up: 1,718 days (4.7 years).

Follow-up (1 entry)
- Days to follow up: 1,718 days (4.7 years); Event-free: no event (relapse, second malignancy or death) recorded through day 1,718; Year of follow up: 2010.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 79.4 ×10³/µL.

Biospecimens (3 samples)
- Samples TARGET-15-SJMPAL012421-09A, TARGET-15-SJMPAL012421-09B (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL012421-14A.1: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 1718
- Protocol: St. Jude
- WBC at Diagnosis: 79.4
- Initial Therapy: AML
- WHO ALAL Classification: T/M
- WHO Dx: T/M
